Gene-level copy-number profile of tumor specimen TCGA-AG-A01N-01A from TCGA case TCGA-AG-A01N, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.6 years (25,049 days).
Specimen TCGA-AG-A01N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.e8c82fb2-5fbd-486e-858e-2007e64e98be.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A01N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b6cf57ab-66c3-4e91-bcd3-004693d8589c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 776; copy number 2: 2; copy number 3: 3,434; copy number 4: 23,683; copy number 5: 16,155; copy number 6: 4,624; copy number 7: 7,491; copy number 8: 47; copy number 9: 702; copy number 10: 1,321; copy number 11: 749; copy number 12: 221; copy number 13: 215; copy number 14: 18; copy number 15: 25; copy number 16: 232; copy number 21: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A01N-01A-01D-A008-01): tumor purity 0.59, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–4): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,513 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:186,311,652–186,375,693, 1 gene, copy number 11 (within-gene range 7–11): TPR.
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 9–16 (broad region; genes not listed).
- chr16:46,469,341–49,900,524, 84 genes, copy number 9 (broad region; genes not listed).
- chr16:78,890,231–78,892,302, 1 gene, copy number 11: AC027279.4.
- chr20:30,484,925–64,313,132, 891 genes, copy number 9–21 (within-gene range 9–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
